Gene-level copy-number profile of tumor specimen TCGA-A7-A0CH-01A from TCGA case TCGA-A7-A0CH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.7 years (29,104 days).
Specimen TCGA-A7-A0CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.05ee789e-dc0f-4f44-a238-84ec5a8207ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0CH-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-A7-A0CH-01A|TCGA-A7-A0CH-10A); AscatNGS (sample pair TCGA-A7-A0CH-01A|TCGA-A7-A0CH-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3cc0d17a-d8be-4c04-9925-f1394ffb1ffb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,201; copy number 2: 54,542; copy number 3: 1,473; copy number 4: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A0CH-01A-21D-A011-01): tumor purity 0.78, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
